Somatic mutation profile of tumor specimen TCGA-DX-A3LS-01A (aliquot TCGA-DX-A3LS-01A-11D-A21Q-09) from TCGA case TCGA-DX-A3LS, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 78.4 years (28,649 days).
Specimen TCGA-DX-A3LS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f781d1c3-610c-44c1-9ffa-2cef9138b521.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3LS-10A (Blood Derived Normal), aliquot TCGA-DX-A3LS-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfeeac13-9f81-4c01-b54f-1a7a0643c73a

The open-access MAF lists 41 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 12, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEL | c.1096G>A p.D366N (on ENST00000673714; = p.D363N on NM_001807.6) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV100672751; called by muse, mutect2, varscan2
- CMSS1 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs767387483, COSV70438491; called by muse, mutect2, varscan2
- FAM186B | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99220130; called by muse, varscan2
- GOLGA3 | c.828C>G p.N276K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as rs1249486638; called by muse, mutect2, varscan2
- IGHV3-30 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.485); catalogued as rs752624147; called by muse, mutect2
- IVL | c.902A>T p.K301M | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.5); catalogued as COSV100908221; called by muse, mutect2, varscan2
- KCNH8 | c.1809G>T p.M603I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as COSV100110917; called by muse, mutect2
- KRT16 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs150387381, COSV100052910; called by muse, mutect2, varscan2
- MAGEB1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs779578367; called by muse, mutect2, varscan2
- MAN1A1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.285); catalogued as COSV63787066; called by muse, varscan2
- METTL1 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV99141551; called by muse, varscan2
- NUP107 | c.1698G>T p.E566D | Missense Mutation (SNP) | VAF 112/1914 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.129); catalogued as COSV99971680; called by muse, mutect2
- PCDHGA4 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1334601429, COSV53895357; called by muse, mutect2, varscan2
- PRB3 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 146/290 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV54393414; called by muse, mutect2, varscan2
- SLC18A2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as rs201547103, COSV53690190; called by muse, mutect2, varscan2
- STKLD1 | c.1604-1G>C p.X535_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100905771; called by mutect2, varscan2
- ZFP57 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761414885, COSV65307178; called by muse, mutect2, varscan2
- FMNL3 | c.2402C>T p.S801F | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FOXI1 | c.550G>C p.V184L | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- LPCAT2 | c.1141del p.I381Lfs*8 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | called by mutect2, pindel, varscan2
- MDM2 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 36/792 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.471); called by muse, mutect2
- PIK3R4 | c.3913C>A p.Q1305K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.035); called by muse, mutect2
- PRPF40B | c.2055G>A p.Q685= (on ENST00000380281; = p.Q672= on NM_012272.3) | Splice Region (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- TRRAP | c.10211C>T p.A3404V (on ENST00000359863 / NM_001244580.1; = p.A3375V on NM_003496.3) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); called by mutect2, varscan2
- TTC37 | c.4550_4551del p.S1517Yfs*18 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- USP48 | c.925A>T p.K309* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- USP6 | c.3320G>C p.S1107T | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- VAV2 | c.782C>G p.S261C (on ENST00000371850 / NM_001134398.2; = p.S256C on NM_003371.4) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ANAPC5 | c.2016G>A p.V672= | Silent (SNP) | VAF 160/237 reads (68%) | called by muse, varscan2
- CEL | c.591G>A p.V197= (on ENST00000673714; = p.V194= on NM_001807.6) | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- ERBB3 | c.465T>G p.L155= | Silent (SNP) | VAF 58/178 reads (33%) | called by muse, mutect2, varscan2
- FMNL3 | c.2988C>T p.I996= | Silent (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- KMT2D | c.13443G>A p.E4481= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- KRT10 | c.229T>C p.L77= | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- METTL1 | c.525C>T p.I175= | Silent (SNP) | VAF 114/328 reads (35%) | called by muse, varscan2
- MYO5C | c.207G>A p.E69= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- PDE8B | c.1812C>T p.I604= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs373238717; called by muse, mutect2, varscan2
- SPACA1 | c.135C>T p.G45= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV52760678; called by muse, mutect2
- STKLD1 | c.1956G>A p.V652= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100905756; called by muse, mutect2
- SYK | c.51C>T p.F17= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs200626943; called by muse, mutect2, varscan2
- RRM1 | c.*2G>T | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
